Somatic mutation profile of tumor specimen TCGA-E8-A419-01A (aliquot TCGA-E8-A419-01A-11D-A23M-08) from TCGA case TCGA-E8-A419, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 31.0 years (11,306 days).
Specimen TCGA-E8-A419-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49c2081e-62f0-431e-89ec-c696c64d619c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E8-A419-10A (Blood Derived Normal), aliquot TCGA-E8-A419-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d7941d7-7adf-4eee-9806-1b37606979a8

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CNTNAP4 | c.1421C>G p.A474G | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.4); catalogued as COSV56680912; called by muse, mutect2
- KMT2A | c.10863A>C p.Q3621H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV63285903; called by muse, mutect2
- LMLN | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57600974; called by muse, mutect2, varscan2
- NOCT | c.1240C>G p.H414D | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54936031; called by muse, mutect2, varscan2
- CFAP43 | c.4141G>T p.V1381L | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.481); called by muse, mutect2
- OR4A47 | c.450A>T p.G150= | Silent (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- SHC3 | c.1677C>A p.V559= | Silent (SNP) | VAF 11/130 reads (8%) | catalogued as COSV65445418; called by muse, mutect2
- ZNF223 | c.150A>G p.Q50= | Silent (SNP) | VAF 72/256 reads (28%) | catalogued as COSV71571890; called by muse, mutect2, varscan2
